Surgical pathology report (de-identified scan), TCGA case TCGA-4X-A9FB, project TCGA-THYM (Thymoma), tissue source site Yale University, specimen TCGA-4X-A9FB-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Procedures/Addenda Attached

Patient: .
MR #.
DOB/Age/Sex:
Visit #.
Submitting Physician:
Other Physicians:

Accession #:
Taken:
Accessioned:
Adm-Disch Date:
Reported:

Clinical History and Impression:

Thymomas. -year-old male with persistent hyperparathyroidism status post work gland parathyroidectomy presents with anterior mediastinal mass.

Specimen(s) Received:

1: THYMUS
2: RIGHT SUPERIOR POLE
3: THYMUS
4: DIAPHRAGM

ICD-O-3
Thymoma, type B2, malignant
Site: Thymus C37.9 8584/3
JW6/24/14

FINAL DIAGNOSIS

1) THYMUS, THYMECTOMY:

- MINIMALLY INVASIVE THYMOMA
- HISTOLOGIC TYPE:
- TYPE B THYMOMA, B2 (CORTICAL)
- TUMOR SIZE (GREATEST DIMENSION): 4 CM
- MARGINS: THYMOMA FOCALLY EXTENDS TO INKED/CAUTERIZED MARGIN
- PATHOLOGIC STAGING: STAGE II (MASAOKA STAGE)
- MICROSCOPIC INVASION INTO SURROUNDING ADIPOSE TISSUE

COMMENT: The thymoma shows focal microscopic invasion into surrounding adipose tissue. The tumor is predominately composed of large polygonal tumor cells exhibiting large vesicular nuclei and predominant nucleoli with a background population of lymphocytes. A single microscopic focus (slide 1-16) shows confluent sheet of tumor cells and many cell with in this areas show markedly enlarged hyperchromatic nuclei reminiscent of anaplasia. However, there is no evidence of increased/atypical mitosis in this area. These changes are interpreted as degenerative changes. Immunostains including Pan-cytokeratin, CD3, Tdt were performed and the results support the above diagnosis. Parathyroid hormone immunostain was also performed and is negative.

Dr and Dr concurs with the diagnosis.

2) RIGHT SUPERIOR POLYP, BIOPSY:

[page 2 of 3]
- HYPERPLASTIC THYMUS, NEGATIVE FOR TUMOR

3) THYMUS BIOPSY:

- THYMIC TISSUE, WITHOUT SIGNIFICANT ABNORMALITY

4) DIAPHRAGM, BIOPSY:

- FRAGMENTS OF BONE AND CARTILAGE
- NEGATIVE FOR TUMOR

Pathologist:

** Report Electronically Signed Out **

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Specimen

Gross Specimen

Gross Description:

1) Received fresh in the frozen section laboratory labeled with the patient's name "thymus" is a 92 g 18.0 x 6.0 x 3.8 cm irregular fatty tissue, grossly consistent with thymus, with a short suture designating inferior and a long suture designating superior. The external capsule is tan smooth and glistening. Within the inferior left segment is a 4.0 x 3.3 x 3.0 cm tan-white fleshy centrally necrotic firm nodule in which a representative section is frozen as FSA, now as cassette one. A representative section is submitted for flow cytometry studies and a representative section is saved frozen for ancillary studies. The remainder of the specimen displays a yellow lobulated fatty tissue surface in which additional nodules are not grossly appreciated. The specimen is formalin fixed and representative sections are submitted as follows: cassettes 2-18 entire tumor sequential from right to left, cassettes 19-22 right arm sequential from superior to inferior, cassettes 23-26 left arm sequential from superior to inferior.

2) Received fresh labeled with the patient's name, MR# and designated "right superior pole" is an unoriented 3.5 x 1 x 0.5 cm piece of red-tan soft tissue which is entirely submitted in one cassette.

3) Received fresh labeled with the patient's name, MR# and designated "thymus" is a 0.5 gram 1.5 x 0.9 x 0.3 cm portion of lobulated yellow soft tissue which is entirely submitted in one cassette.

4) Received fresh labeled with the patient's name, MR# and designated "diaphragm" is a 1.5 x 1 x 0.3 cm portion of cartilage which is serially sectioned and entirely submitted in one cassette following decalcification.

Frozen/Intraoperative Diagnosis:

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Thymus: Thymoma, classification deferred for complete evaluation of margins. Findings reported to Dr. in person. [1 block]

Summary of Stains Performed and Reviewed	Count
CD3 *	1
H&E, Recut, Level	13
Keratin, AE1/AE3 PK *	1
Negative Control *	2
Parathyroid Hormone *	1
TdT *	1

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and Internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination	Block Detail			
	# Blocks	Designation	#	Description
Part 1] THYMUS	26	FSA	(1)	(No Description)
		L	(5)	(No Description)
		R	(4)	(No Description)
		T	(16)	Tumor
Part 2] RIGHT SUPERIOR POLE	1	[Undes]	(1)	(No Description)
Part 3] THYMUS	1	[Undes]	(1)	(No Description)
Part 4] DIAPHRAGM	1	[Undes]	(1)	(No Description)
Total:	29			

Procedures/Addenda

ADDITIONAL STUDIES

Status: Signed Out

Pathologist:

Ordered:

Reported:

Interpretation

At Dr request, status of margin reviewed. reviewed all of the slides of the case. The slides thought by to show cautery are now thought to show edge air drying effect. The three blocks with the most suspicious areas for margin involvement on ink are recut. These deeper sections are reviewed by These sections show tumor close to margin but not transected. Preliminary status of review discussed with Dr and discussed at

Printed by:

END OF REPORT

Source: NCI Genomic Data Commons file d8d58203-8af1-4b55-ad92-c75a21c7b69d (TCGA-4X-A9FB.C2D0B379-A081-4E48-AD0F-86C6B7412E29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).